Somatic mutation profile of tumor specimen TCGA-CC-A123-01A (aliquot TCGA-CC-A123-01A-11D-A12Z-10) from TCGA case TCGA-CC-A123, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 24.9 years (9,107 days).
Specimen TCGA-CC-A123-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16964037-2065-4d5a-ac6a-6504c996108d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A123-10A (Blood Derived Normal), aliquot TCGA-CC-A123-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2874007-c6c7-4fe2-8319-18a5834ea12c

The open-access MAF lists 84 somatic variants for this specimen: 63 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 18, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 2, Frame Shift Ins 1, 5'UTR 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC100868.1 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV51839518; called by muse, mutect2, varscan2
- ADAM17 | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV60397954; called by muse, mutect2
- ADGRG2 | c.2336G>T p.W779L (on ENST00000379869 / NM_001079858.3; = p.W776L on NM_005756.4) | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61338009; called by muse, mutect2, varscan2
- AP3D1 | c.1411A>C p.S471R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV100642418, COSV61425518; called by muse, mutect2, varscan2
- ASNS | c.46G>C p.V16L | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as COSV51550996; called by muse, mutect2, varscan2
- BBOX1 | c.566C>A p.A189E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as COSV54189832; called by muse, mutect2, varscan2
- BRPF1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs762698085, COSV57403655; called by muse, mutect2, varscan2
- CCDC39 | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV56480216; called by muse, mutect2
- CCND2 | c.57C>A p.N19K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.036); catalogued as COSV54222176; called by muse, mutect2, varscan2
- CDH26 | c.807C>A p.N269K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754090670, COSV54844064; called by muse, mutect2, varscan2
- CFAP46 | c.5913C>A p.D1971E | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV54150052; called by muse, mutect2, varscan2
- CHAF1B | c.1289C>A p.P430H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV58439444; called by muse, mutect2, varscan2
- COL16A1 | c.4174G>A p.G1392S | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs749754753, COSV54702033; called by muse, mutect2, varscan2
- CSMD3 | c.3184A>G p.T1062A (on ENST00000297405 / NM_001363185.1; = p.T958A on NM_052900.3) | Missense Mutation (SNP) | VAF 78/343 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as rs1275626732, COSV52126752, COSV99849922; called by muse, mutect2, varscan2
- CYLC1 | c.1161G>T p.L387F | Missense Mutation (SNP) | VAF 95/181 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV100255530, COSV61410707; called by muse, mutect2, varscan2
- DNAJC4 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54172584; called by muse, mutect2, varscan2
- ELAC2 | c.2314G>C p.A772P | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52390656; called by muse, mutect2, varscan2
- FAM13C | c.602C>A p.P201Q | Missense Mutation (SNP) | VAF 119/234 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV53244901; called by muse, mutect2, varscan2
- FRMD7 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 103/224 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs752045112, COSV53745146; called by muse, mutect2, varscan2
- GABRA1 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50098576, COSV99195690; called by muse, mutect2, varscan2
- GALNT8 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as COSV52895462, COSV52902100; called by muse, mutect2, varscan2
- GAS2L2 | c.1568C>T p.T523I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs1441975487; called by muse, mutect2, varscan2
- GMPS | c.1495A>T p.M499L | Missense Mutation (SNP) | VAF 620/915 reads (68%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV55808376; called by muse, mutect2, varscan2
- GOLGA4 | c.3431A>G p.N1144S | Missense Mutation (SNP) | VAF 117/213 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs758806004, COSV62709717; called by muse, mutect2, varscan2
- HDAC2 | c.1311T>A p.D437E | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV64037551; called by muse, mutect2, varscan2
- HECW1 | c.1579T>A p.S527T | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV67824894; called by muse, mutect2, varscan2
- IL17REL | c.69C>G p.C23W | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771026898, COSV100377450, COSV58007839; called by muse, mutect2, varscan2
- IL21R | c.214C>A p.H72N | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV61969112; called by muse, mutect2, varscan2
- IVL | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs933809767, COSV64215795; called by muse, mutect2, varscan2
- LMAN1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs760200001, COSV51826172; called by muse, mutect2, varscan2
- MICAL3 | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99263327; called by muse, mutect2, varscan2
- MUC7 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 195/276 reads (71%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.479); catalogued as rs1308397960, COSV100512432; called by muse, mutect2, varscan2
- MVB12B | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV63257061; called by muse, varscan2
- MYCN | c.34A>G p.M12V | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV55257976; called by muse, mutect2, varscan2
- MYO1G | c.2226G>A p.W742* | Nonsense Mutation (SNP) | VAF 13/22 reads (59%) | catalogued as COSV51853671; called by muse, mutect2, varscan2
- NLRP6 | c.1321G>C p.D441H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV56458558; called by muse, mutect2, varscan2
- OR1A2 | c.646T>C p.S216P | Missense Mutation (SNP) | VAF 31/351 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67936205, COSV67936378; called by muse, mutect2
- OR4N5 | c.873C>A p.N291K | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV61320224; called by muse, mutect2, varscan2
- OR4Q3 | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 156/755 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV59177658; called by muse, mutect2, varscan2
- PCDHGB2 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV53914251; called by muse, mutect2, varscan2
- PLEKHG5 | c.1570C>T p.R524W (on ENST00000400915 / NM_001042663.3; = p.R487W on NM_020631.6) | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61067878; called by muse, mutect2, varscan2
- PLXNA4 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as rs200648753, COSV58111797; called by muse, mutect2, varscan2
- POMT2 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.724); catalogued as rs148466370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRRT1 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV52997644; called by muse, mutect2
- PSPC1 | c.1420C>A p.Q474K | Missense Mutation (SNP) | VAF 44/596 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.678); catalogued as COSV58887122; called by muse, mutect2
- RAB40A | c.119A>T p.E40V | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV58490828; called by muse, mutect2, varscan2
- RLIM | c.1259T>A p.M420K | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV60325629; called by muse, mutect2, varscan2
- RXRB | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV63399547; called by muse, mutect2, varscan2
- SLC34A3 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1161944832, COSV63186652; called by muse, mutect2
- STKLD1 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64241283; called by muse, mutect2, varscan2
- STRADA | c.715A>G p.K239E (on ENST00000336174 / NM_001363786.1; = p.K202E on NM_153335.6) | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.515); catalogued as COSV55561843; called by muse, mutect2, varscan2
- STX16 | c.656C>A p.T219K (on ENST00000371141 / NM_001001433.3; = p.T198K on NM_003763.6) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV56604597; called by muse, varscan2
- TMTC2 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 51/146 reads (35%) | catalogued as COSV58262205; called by muse, mutect2, varscan2
- TPO | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV61097185; called by muse, mutect2, varscan2
- TRABD2A | c.926G>C p.G309A (on ENST00000409520 / NM_001277053.2; = p.G260A on NM_001080824.3) | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.303); catalogued as COSV59102197, COSV59104846; called by muse, mutect2, varscan2
- TTN | c.47803C>T p.P15935S (on ENST00000591111; = p.P8511S on NM_003319.4) | Missense Mutation (SNP) | VAF 75/165 reads (45%) | PolyPhen possibly damaging (0.859); catalogued as COSV59935619; called by muse, mutect2, varscan2
- ZDHHC1 | c.871G>C p.A291P | Missense Mutation (SNP) | VAF 68/84 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV52083569, COSV99339512; called by muse, mutect2, varscan2
- ZNF335 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772818462, COSV59816586; called by muse, mutect2, varscan2
- ARID1A | c.6697_6698dup p.A2234Gfs*34 | Frame Shift Ins (INS) | VAF 12/18 reads (67%) | called by mutect2, varscan2
- EHBP1L1 | c.2063_2078del p.L688Qfs*32 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- IL6ST | c.575_583del p.V192_I194del | In Frame Del (DEL) | VAF 114/284 reads (40%) | called by mutect2, pindel, varscan2
- LCE1E | c.197del p.G66Afs*12 | Frame Shift Del (DEL) | VAF 27/113 reads (24%) | called by mutect2, pindel, varscan2
- PCDH15 | c.542_544del p.D181del | In Frame Del (DEL) | VAF 52/134 reads (39%) | called by pindel, varscan2
- ACADVL | c.1143G>A p.E381= | Silent (SNP) | VAF 61/83 reads (73%) | catalogued as COSV50034969; called by muse, mutect2, varscan2
- ARAP3 | c.3774G>T p.L1258= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV53349325; called by muse, mutect2, varscan2
- B3GAT2 | c.672C>T p.N224= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs371527631, COSV57769270; called by muse, mutect2, varscan2
- CHRNB4 | c.66C>G p.R22= | Silent (SNP) | VAF 95/107 reads (89%) | catalogued as COSV55715064, COSV55718150; called by muse, mutect2, varscan2
- CTNNA2 | c.2538A>T p.G846= | Silent (SNP) | VAF 12/208 reads (6%) | catalogued as COSV100562442; called by muse, mutect2
- DDHD1 | c.801T>C p.D267= (on ENST00000323669; = p.D464= on NM_030637.3) | Silent (SNP) | VAF 67/174 reads (39%) | catalogued as rs1363844838, COSV60357835; called by muse, mutect2, varscan2
- HMX3 | c.777C>T p.G259= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs772496101, COSV63501533; called by muse, mutect2, varscan2
- LCN2 | c.204G>A p.P68= | Silent (SNP) | VAF 104/213 reads (49%) | catalogued as rs775328996, COSV52979726; called by muse, mutect2, varscan2
- NPHS1 | c.1107G>A p.R369= | Silent (SNP) | VAF 44/175 reads (25%) | catalogued as COSV62286836; called by muse, mutect2, varscan2
- NTRK3 | c.1893C>A p.A631= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV100712448, COSV62298180; called by muse, mutect2, varscan2
- RFX1 | c.597C>T p.T199= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as COSV54328305; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.6G>A p.K2= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as COSV59562882; called by muse, mutect2, varscan2
- SYNE2 | c.9411C>T p.L3137= | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as COSV59942786; called by muse, mutect2, varscan2
- TRPS1 | c.1356A>T p.L452= (on ENST00000220888 / NM_001330599.2; = p.L465= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/230 reads (26%) | catalogued as COSV55230381; called by muse, mutect2, varscan2
- TUBB8 | c.126G>T p.L42= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV59115019; called by muse, mutect2, varscan2
- USP54 | c.2814A>G p.P938= | Silent (SNP) | VAF 128/242 reads (53%) | catalogued as COSV60440591; called by muse, mutect2, varscan2
- YIPF2 | c.501C>T p.I167= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV53402960; called by muse, mutect2, varscan2
- ZCWPW2 | c.939A>T p.A313= | Silent (SNP) | VAF 76/302 reads (25%) | catalogued as COSV67497966, COSV67499759; called by muse, mutect2, varscan2
- DENND10P1 | n.725_730del | RNA (DEL) | VAF 91/324 reads (28%) | called by mutect2, pindel, varscan2
- PDXK | c.88-1691A>G | Intron (SNP) | VAF 56/117 reads (48%) | catalogued as COSV99376821; called by muse, mutect2, varscan2
- RUSC1 | c.-151C>A | 5'UTR (SNP) | VAF 12/38 reads (32%) | catalogued as rs745696830, COSV52738642; called by muse, mutect2, varscan2
